Gene-level copy-number profile of tumor specimen TCGA-MT-A51X-01A from TCGA case TCGA-MT-A51X, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 30.1 years (10,976 days).
Specimen TCGA-MT-A51X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.6a249a63-91d1-4ada-b35d-6a59c6f491fc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-MT-A51X-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/efe9d52d-b588-4fa1-9724-12c8fb3a9a81

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 50; copy number 1: 275; copy number 2: 13,623; copy number 3: 29,386; copy number 4: 9,879; copy number 5: 3,563; copy number 6: 993; copy number 7: 1,831; copy number 11: 196; copy number 16: 3; copy number 29: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MT-A51X-01A-11D-A25X-01): tumor purity 0.45, ploidy 3.31, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:78,758,974–78,938,292, 2 genes: AC055731.1, RN7SL751P.
- chr9:33,634,111–33,920,399, 18 genes (within-gene range 0–7): TRBV22OR9-2, TRBV23OR9-2, TRBV24OR9-2, TRBV25OR9-2, PTENP1, PTENP1-AS, TRBV26OR9-2, AL356489.2, AL356489.3, AL356489.1, AL356489.4, LINC01251, PRSS3, UBE2R2-AS1, TRBV29OR9-2, UBE2R2, Y_RNA, RNU4ATAC11P.
- chr9:35,962,195–37,034,268, 23 genes: OR2S1P, YBX1P10, OR13C6P, OR13C7, OR2AM1P, RECK, AL138834.1, GLIPR2, CCIN, CLTA, GNE, RNU4-53P, HMGB3P24, RNF38, MELK, AL442063.1, AL450267.2, MIR4475, PAX5, AL450267.1, MIR4540, MIR4476, AL161781.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,045 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,028,804–103,332,866, 922 genes, copy number 7 (broad region; genes not listed).
- chr8:106,980,967–145,066,685, 570 genes, copy number 7 (broad region; genes not listed).
- chr9:33,921,693–35,405,338, 69 genes, copy number 7–11 (broad region; genes not listed).
- chr11:54,682,877–64,001,811, 466 genes, copy number 7–11 (broad region; genes not listed).
- chr11:70,270,690–71,252,577, 18 genes, copy number 16–29 (within-gene range 1–29): PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664.

Autosomal genes at a single copy (total copy number 1): 275. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
